Somatic mutation profile of tumor specimen TCGA-CZ-5985-01A (aliquot TCGA-CZ-5985-01A-11D-1669-08) from TCGA case TCGA-CZ-5985, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.2 years (21,242 days).
Specimen TCGA-CZ-5985-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f262faeb-8172-4a76-b6a1-461353d74ca4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5985-11A (Solid Tissue Normal), aliquot TCGA-CZ-5985-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66314868-6d3b-4fba-990f-ebaa05518bbd

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 31, Silent 12, Frame Shift Del 4, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGGF1 | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV57229552; called by muse, mutect2, varscan2
- ARHGAP35 | c.2740del p.E914Kfs*34 | Frame Shift Del (DEL) | VAF 29/134 reads (22%) | catalogued as COSV68330154; called by pindel, varscan2
- ARHGEF6 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.829); catalogued as COSV51692317; called by muse, mutect2, varscan2
- ATF7IP2 | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61093990; called by muse, mutect2, varscan2
- BAP1 | c.932-1G>T p.X311_splice | Splice Site (SNP) | VAF 41/105 reads (39%) | catalogued as COSV56235716, COSV56239408; called by muse, mutect2, varscan2
- BDH2 | c.84A>T p.R28S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56478733; called by muse, mutect2, varscan2
- CDH23 | c.4958G>T p.S1653I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56470803; called by muse, mutect2, varscan2
- CDH23 | c.9751G>A p.E3251K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.137); catalogued as COSV56470815; called by muse, varscan2
- DEPDC5 | c.1081+1G>C p.X361_splice | Splice Site (SNP) | VAF 42/136 reads (31%) | catalogued as COSV56700554; called by muse, mutect2, varscan2
- DNTT | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV64523147; called by muse, mutect2, varscan2
- EPHA8 | c.108C>A p.D36E | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV51272784; called by muse, mutect2, varscan2
- EPHA8 | c.109A>C p.T37P | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV51272873; called by muse, varscan2
- FAM219A | c.257G>A p.R86Q (on ENST00000445726; = p.R69Q on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs777204338, COSV52620704, COSV52621205; called by muse, mutect2, varscan2
- GPR61 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as COSV68177761; called by muse, mutect2, varscan2
- GTF3C1 | c.2886T>G p.I962M | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV62242049; called by muse, mutect2, varscan2
- HMCN1 | c.12945T>G p.I4315M | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV54909061; called by muse, mutect2, varscan2
- HRC | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53256937; called by muse, mutect2, varscan2
- HUWE1 | c.4600A>T p.T1534S | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV53350428; called by muse, mutect2, varscan2
- KCNC4 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1190326099, COSV63925886; called by muse, mutect2, varscan2
- KMT2E | c.4194G>T p.E1398D | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV57575076; called by muse, mutect2, varscan2
- LRRC19 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV66259569, COSV66259728; called by muse, mutect2, varscan2
- MAU2 | c.866G>T p.C289F | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV53235988; called by muse, mutect2, varscan2
- MEMO1 | c.866A>T p.Y289F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54453435; called by muse, mutect2
- NIPBL | c.6120T>A p.D2040E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.189); catalogued as COSV56955075; called by muse, varscan2
- PCLO | c.746C>A p.S249* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as COSV61642040; called by muse, mutect2, varscan2
- PODN | c.407G>T p.R136L (on ENST00000395871; = p.R88L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as COSV57011422, COSV57014519; called by muse, mutect2, varscan2
- POLR1B | c.698C>A p.T233N | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV54494417, COSV54499545; called by muse, mutect2, varscan2
- PREX1 | c.2876C>T p.P959L | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV64253057; called by muse, mutect2, varscan2
- RBM17 | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.217); catalogued as COSV65913945; called by muse, mutect2, varscan2
- SDK1 | c.4111G>C p.E1371Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs1425526722, COSV67373691; called by muse, mutect2, varscan2
- SLC2A14 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV61587011; called by muse, mutect2
- SLITRK6 | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 46/175 reads (26%) | catalogued as rs772203918, COSV68390342; called by muse, mutect2, varscan2
- SPG7 | c.843A>T p.E281D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV51951466; called by muse, mutect2, varscan2
- TMF1 | c.3084T>G p.N1028K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV68374600; called by muse, mutect2, varscan2
- TMPRSS15 | c.1179C>A p.Y393* | Nonsense Mutation (SNP) | VAF 32/142 reads (23%) | catalogued as COSV53041762; called by muse, varscan2
- VHL | c.330_331dup p.S111Tfs*49 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | catalogued as COSV56546745; called by mutect2, pindel, varscan2
- ZNF615 | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65033872; called by muse, mutect2, varscan2
- ACSM5 | c.863dup p.N288Kfs*9 | Frame Shift Ins (INS) | VAF 29/123 reads (24%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.2883_2884del p.T962Nfs*7 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | called by mutect2, pindel, varscan2
- MYLK | c.3453del p.L1152Sfs*20 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel*, varscan2
- OBSCN | c.21056C>A p.P7019Q | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- TRAV27 | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZNF398 | c.880del p.S294Qfs*13 (on ENST00000475153 / NM_170686.3; = p.S123Qfs*13 on NM_020781.4) | Frame Shift Del (DEL) | VAF 101/361 reads (28%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.118A>C p.R40= (on ENST00000366508; = p.R14= on NM_015446.5) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs751362444, COSV58251519; called by muse, mutect2, varscan2
- ATP8A1 | c.933C>A p.V311= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV52538027; called by muse, mutect2, varscan2
- C19orf57 | c.1497G>A p.Q499= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV60968769; called by muse, mutect2, varscan2
- DSCAML1 | c.4371G>T p.S1457= (on ENST00000321322; = p.S1397= on NM_020693.4) | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV58393989, COSV58399773; called by muse, mutect2, varscan2
- EMCN | c.777C>A p.T259= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as rs1560603464, COSV56460075; called by muse, mutect2, varscan2
- GAPVD1 | c.2718A>T p.V906= (on ENST00000394104; = p.V933= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV52924054; called by muse, mutect2, varscan2
- HSPA9 | c.546G>A p.L182= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs751963587, COSV51864773; called by muse, mutect2, varscan2
- KIF26B | c.1152C>T p.A384= | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as COSV69465108; called by muse, mutect2, varscan2
- PADI6 | c.2061C>T p.F687= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100639877, COSV61885006; called by muse, mutect2, varscan2
- SLC8A2 | c.211C>A p.R71= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52639801, COSV52640383; called by muse, mutect2, varscan2
- ST3GAL3 | c.760T>C p.L254= (on ENST00000361392 / NM_174964.4; = p.L239= on NM_006279.5) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV53515288; called by muse, mutect2, varscan2
- TLL1 | c.906C>T p.N302= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV50292995; called by muse, mutect2, varscan2
